Somatic mutation profile of tumor specimen TCGA-EM-A3SU-01A (aliquot TCGA-EM-A3SU-01A-11D-A22Z-08) from TCGA case TCGA-EM-A3SU, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 43.2 years (15,768 days).
Specimen TCGA-EM-A3SU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7256a57e-9d22-443d-9ffc-676237e48be0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3SU-10A (Blood Derived Normal), aliquot TCGA-EM-A3SU-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7098b608-db33-4d37-8a96-e2f19b05bce8

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 9, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CCT6B | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100030673, COSV58488266, COSV58490017; called by muse, mutect2
- CILP | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.63); catalogued as COSV99973405; called by muse, mutect2
- DDX46 | c.2612A>G p.D871G | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV100844876; called by muse, mutect2, varscan2
- IRS2 | c.2262G>T p.E754D | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as COSV101019107; called by muse, mutect2
- PDSS1 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as COSV100873582; called by muse, mutect2
- SACS | c.4055G>A p.S1352N | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as rs1379038246, COSV101207446; called by muse, mutect2
- LARP7 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- SEMA5A | c.1864T>C p.C622R | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCT6B | c.75C>T p.C25= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV100030674; called by muse, mutect2
- RARRES2 | c.216G>A p.L72= | Silent (SNP) | VAF 20/504 reads (4%) | catalogued as COSV99784649; called by muse, mutect2
- SEPTIN12 | c.405G>A p.E135= | Silent (SNP) | VAF 37/120 reads (31%) | catalogued as COSV99190648; called by muse, mutect2, varscan2
